Somatic mutation profile of tumor specimen TARGET-40-NAAEDI-08A (aliquot TARGET-40-NAAEDI-08A-01D) from TARGET case TARGET-40-NAAEDI, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 15.5 years (5,663 days).
Specimen TARGET-40-NAAEDI-08A: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef86c8bc-bd18-4e05-baec-d2a315646ac9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDI-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17a7dc1f-ad80-4a69-a716-05e7b11593ed

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYNE2 | c.1031A>T p.K344M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV59944349; called by muse, mutect2, varscan2
- DNAH9 | c.8401G>A p.E2801K | Missense Mutation (SNP) | VAF 321/1249 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DNAH9 | c.6924G>A p.Q2308= | Silent (SNP) | VAF 192/905 reads (21%) | called by muse, mutect2, varscan2
- ACMSD | c.580+9C>T | Intron (SNP) | VAF 25/116 reads (22%) | catalogued as rs777196076, COSV51607932, COSV51608736; called by muse, mutect2, varscan2
